Gene-level copy-number profile of tumor specimen CUPP-B45F-TTM1-A from CCG case CUPP-B45F, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 37.7 years (13,762 days).
Specimen CUPP-B45F-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3e61d718-69f4-4e03-8202-ebcbcbc3f12a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B45F-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/73c26669-98c4-4350-8154-a5a677408fd3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 6,042; copy number 2: 45,233; copy number 3: 6,251; copy number 4: 570; copy number 5: 187; copy number 6: 108; copy number 7: 1; copy number 8: 2; copy number 11: 1; copy number 15: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:61,658,474–61,698,432, 2 genes (within-gene range 0–1): AC026746.1, RNU6-913P.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr11:55,262,155–55,271,114, 2 genes: TRIM48, AP005597.4.
- chr17:2,117,626–2,117,772, 1 gene (within-gene range 0–2): AC090617.8.
- chr19:41,386,374–41,397,359, 1 gene (within-gene range 0–1): EXOSC5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 301 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:1,459,937–1,464,008, 1 gene, copy number 15: AC102953.1.
- chr7:1,470,277–1,571,005, 5 genes, copy number 7–20 (within-gene range 2–20): INTS1, AC093734.1, MAFK, TMEM184A, PSMG3.
- chr8:47,736,913–48,194,627, 8 genes, copy number 6: CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1.
- chr8:141,117,278–145,066,685, 186 genes, copy number 5 (broad region; genes not listed).
- chr16:13,246,232–16,398,594, 100 genes, copy number 6 (broad region; genes not listed).
- chr19:38,535,517–38,537,128, 1 gene, copy number 5 (within-gene range 4–5): AC067969.1.

Autosomal genes at a single copy (total copy number 1): 3,698. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
